Somatic mutation profile of tumor specimen TCGA-AR-A2LK-01A (aliquot TCGA-AR-A2LK-01A-11D-A17W-09) from TCGA case TCGA-AR-A2LK, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 62.4 years (22,800 days).
Specimen TCGA-AR-A2LK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07a7a631-1be6-4245-aebd-b000b67fc3af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A2LK-10A (Blood Derived Normal), aliquot TCGA-AR-A2LK-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/471df009-8c69-493b-bffb-381df7e04fcc

The open-access MAF lists 42 somatic variants for this specimen: 30 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 27, Silent 12, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 71/85 reads (84%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.2381C>A p.T794K | Missense Mutation (SNP) | VAF 64/132 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as rs1242301748, COSV52200780; called by muse, mutect2, varscan2
- BIRC7 | c.207G>T p.E69D | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV53901096; called by muse, mutect2, varscan2
- CBLL2 | c.692T>A p.F231Y | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.428); catalogued as COSV60368973; called by muse, mutect2, varscan2
- CCN4 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as rs377237188; called by muse, mutect2, varscan2
- CDH20 | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1246582371, COSV53009414; called by muse, mutect2, varscan2
- CNTN3 | c.207T>G p.I69M | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV55170665; called by muse, mutect2, varscan2
- CPNE6 | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as rs1356633648, COSV53742732; called by muse, mutect2, varscan2
- DCPS | c.184A>T p.I62F | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV55010819; called by muse, mutect2, varscan2
- DOK2 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs546091332, COSV52388457; called by muse, mutect2, varscan2
- DPP4 | c.1051A>G p.T351A | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as rs755540270, COSV62106592; called by muse, mutect2, varscan2
- DSG3 | c.88A>C p.K30Q | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV57126117; called by mutect2, varscan2
- FAM83H | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 53/76 reads (70%) | SIFT tolerated (0.22); PolyPhen benign (0.159); catalogued as rs782421757, COSV66353866; called by muse, mutect2, varscan2
- FAT3 | c.6896C>A p.A2299E | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV99962536; called by muse, mutect2
- FCGBP | c.3085G>A p.G1029R | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1396139682; called by muse, mutect2, varscan2
- FLG | c.2690G>A p.R897H | Missense Mutation (SNP) | VAF 94/503 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.202); catalogued as rs200062706, COSV64241578; called by muse, mutect2, varscan2
- HHIPL2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT tolerated (0.6); PolyPhen benign (0.026); catalogued as COSV58563207; called by muse, mutect2, varscan2
- IL22RA2 | c.256del p.I86Ffs*50 | Frame Shift Del (DEL) | VAF 25/130 reads (19%) | catalogued as COSV51663375; called by mutect2, pindel, varscan2
- OR5AC2 | c.702G>T p.K234N | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV62279462; called by muse, mutect2, varscan2
- OTOA | c.1124G>T p.G375V (on ENST00000286149; = p.G361V on NM_144672.4) | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1381926617, COSV53753667; called by muse, mutect2, varscan2
- PRR27 | c.75G>T p.E25D | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as COSV60640532; called by muse, mutect2, varscan2
- RHOC | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV53517538; called by muse, mutect2, varscan2
- SYNE1 | c.12056C>T p.A4019V (on ENST00000367255 / NM_182961.4; = p.A3948V on NM_033071.3) | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756840607, COSV54975755; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TLX2 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52045882; called by muse, mutect2, varscan2
- TMPRSS6 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as COSV60977876; called by muse, mutect2, varscan2
- WDR13 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.812); catalogued as rs1556993836, COSV54331732; called by muse, mutect2, varscan2
- ZDHHC9 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs1165364635, COSV64096565; called by muse, mutect2, varscan2
- ZFAND4 | c.827G>C p.G276A | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV60858961; called by muse, mutect2, varscan2
- ZSCAN21 | c.178C>T p.R60* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as rs747883825, COSV52850529; called by muse, mutect2, varscan2
- CDH1 | c.2363_2376del p.A788Efs*14 | Frame Shift Del (DEL) | VAF 39/54 reads (72%) | called by mutect2, pindel, varscan2
- ADAM17 | c.1908C>T p.D636= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as rs776882539, COSV60398719; called by muse, mutect2, varscan2
- C7orf57 | c.768T>A p.G256= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV62362704; called by muse, mutect2, varscan2
- CFAP91 | c.672G>A p.T224= | Silent (SNP) | VAF 77/93 reads (83%) | catalogued as rs753051761, COSV56340870; called by muse, mutect2, varscan2
- CHRNB4 | c.1176C>T p.P392= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs142694602; called by muse, mutect2, varscan2
- GJD2 | c.750G>A p.K250= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as COSV51748130, COSV99290872; called by muse, mutect2, varscan2
- LARP1 | c.732G>A p.K244= (on ENST00000518297 / NM_033551.3; = p.K167= on NM_015315.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 57/138 reads (41%) | catalogued as COSV60426938; called by muse, mutect2, varscan2
- NOX4 | c.1308T>C p.T436= | Silent (SNP) | VAF 23/32 reads (72%) | catalogued as COSV54452766; called by muse, mutect2, varscan2
- NTNG2 | c.405C>T p.D135= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs1564408290, COSV62364085, COSV62366514; called by muse, mutect2
- SCN4A | c.4617C>T p.D1539= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs772431686, COSV71126791; ClinVar: likely benign; called by muse, mutect2, varscan2
- STX17 | c.694C>T p.L232= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV52283611; called by muse, mutect2, varscan2
- ZBTB39 | c.1938G>A p.S646= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs376154391; called by mutect2, varscan2
- ZIC3 | c.249C>T p.N83= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as rs1323645838, COSV54972686; called by muse, mutect2, varscan2
